Somatic mutation profile of tumor specimen TCGA-C5-A1ME-01A (aliquot TCGA-C5-A1ME-01A-11D-A13W-08) from TCGA case TCGA-C5-A1ME, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G1; Age at diagnosis: 41.0 years (14,970 days).
Specimen TCGA-C5-A1ME-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f5d6d4b8-12f5-47bd-bbd0-bc332f36c91b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-C5-A1ME-10A (Blood Derived Normal), aliquot TCGA-C5-A1ME-10A-01D-A13W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/30a6aee5-61c4-469e-9f17-3058cb222c24

The open-access MAF lists 72 somatic variants for this specimen: 54 protein-altering or splice-affecting, 15 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 15, Nonsense Mutation 2, Intron 2, RNA 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 19/41 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB6 | c.2386G>A p.V796I | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753788507, COSV54694689; called by muse, mutect2, varscan2
- ABCC3 | c.2501C>T p.P834L | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as rs369718940; called by muse, mutect2, varscan2
- AHCYL1 | c.1213G>A p.D405N | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.429); catalogued as rs538566120, COSV63208242; called by muse, mutect2, varscan2
- ARHGAP4 | c.971T>C p.V324A | Missense Mutation (SNP) | VAF 9/136 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV100603885; called by muse, mutect2
- ATP6V0D1 | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV52096865; called by muse, mutect2, varscan2
- CBX4 | c.1000G>A p.G334R | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs760922762, COSV53964496; called by muse, mutect2, varscan2
- CCDC148 | c.875A>G p.Y292C | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1258067047, COSV51754847; called by muse, mutect2, varscan2
- CDH11 | c.959C>T p.T320M | Missense Mutation (SNP) | VAF 57/220 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs373083222; called by muse, mutect2, varscan2
- CHRNG | c.489C>A p.N163K | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67315272; called by muse, mutect2, varscan2
- CNTNAP3 | c.3835G>A p.E1279K | Missense Mutation (SNP) | VAF 32/523 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.27); catalogued as COSV99904255; called by muse, mutect2
- COL11A2 | c.1364G>A p.R455Q (on ENST00000341947 / NM_080680.3; = p.R348Q on NM_080679.2) | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.992); catalogued as rs781138300, COSV100553531; called by muse, mutect2
- CREB3L4 | c.517G>A p.V173I | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs762042967, COSV55131447; called by muse, mutect2, varscan2
- CSF2RB | c.2461G>A p.D821N | Missense Mutation (SNP) | VAF 43/156 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs146598061; called by muse, mutect2, varscan2
- DENND2C | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs772944552, COSV67920142; called by muse, mutect2, varscan2
- DZIP1 | c.344C>T p.P115L | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100714018; called by muse, mutect2
- EDAR | c.339T>A p.C113* | Nonsense Mutation (SNP) | VAF 3/40 reads (8%) | catalogued as COSV99303179; called by muse, mutect2
- ENDOD1 | c.478C>G p.L160V | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99566390; called by muse, mutect2
- FA2H | c.703C>T p.R235C | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs387907039, CM102273, COSV54725314; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- FAM214A | c.3004G>A p.V1002M | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55921673, COSV55922296; called by muse, mutect2, varscan2
- FBXO38 | c.832C>G p.L278V | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99693151; called by muse, mutect2
- GNAI2 | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs781807470, COSV56492774; called by muse, mutect2, varscan2
- GPR153 | c.440T>C p.V147A | Missense Mutation (SNP) | VAF 4/107 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100928467; called by muse, mutect2
- H4C3 | c.31T>A p.L11M | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.456); catalogued as COSV100619491, COSV100619586; called by muse, mutect2, varscan2
- HLA-E | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV64927244; called by muse, mutect2, varscan2
- INTS1 | c.4711G>A p.A1571T | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.001); catalogued as COSV67176450; called by muse, mutect2, varscan2
- KIAA1109 | c.9679G>A p.E3227K | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.1); catalogued as COSV52663112; called by muse, mutect2
- KRT2 | c.1682G>T p.G561V | Missense Mutation (SNP) | VAF 10/320 reads (3%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.974); catalogued as COSV100548321; called by muse, mutect2
- KRT31 | c.365C>T p.S122F | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as COSV52433534; called by muse, mutect2, varscan2
- LGR6 | c.1525A>G p.K509E (on ENST00000367278 / NM_001017403.1; = p.K457E on NM_021636.3) | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.576); catalogued as COSV55151929; called by muse, mutect2
- LY75 | c.2077G>A p.E693K | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55105721; called by muse, mutect2
- MST1R | c.2113G>C p.E705Q | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.099); catalogued as CM164569, COSV99617951; called by muse, mutect2, varscan2
- MUC3A | c.508G>A p.V170I | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated, low confidence (0.36); catalogued as rs756522792, COSV100114076; called by muse, mutect2, varscan2
- NTN4 | c.1519G>T p.E507* | Nonsense Mutation (SNP) | VAF 11/36 reads (31%) | catalogued as COSV59217355; called by muse, mutect2, varscan2
- NTRK3 | c.1636G>A p.E546K | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100712331; called by muse, mutect2
- OGA | c.1829G>T p.R610L | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV63381010; called by muse, mutect2, varscan2
- PAX7 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs768503948, COSV64748624; called by muse, mutect2, varscan2
- PIAS2 | c.1438G>A p.E480K | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as rs1186605438, COSV100244843, COSV61342239; called by muse, mutect2, varscan2
- RAB3IP | c.582A>C p.E194D (on ENST00000550536 / NM_175623.4; = p.E178D on NM_022456.5) | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56081906; called by muse, mutect2, varscan2
- RTN1 | c.791T>C p.I264T | Missense Mutation (SNP) | VAF 5/142 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV99954826; called by muse, mutect2
- SKIV2L | c.508C>T p.R170W | Missense Mutation (SNP) | VAF 11/140 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs150758406; called by muse, mutect2
- SLC4A1 | c.856G>T p.A286S | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (1); PolyPhen possibly damaging (0.469); catalogued as COSV99293042; called by muse, mutect2, varscan2
- SPANXB1 | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 33/678 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.982); catalogued as rs1263884495; called by muse, mutect2
- STRAP | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 9/146 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.164); catalogued as COSV50308836, COSV99214673; called by muse, mutect2
- TESK1 | c.787C>T p.R263C | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52410293; called by muse, mutect2, varscan2
- TRIM58 | c.1066G>T p.A356S | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.05); catalogued as COSV63569176; called by muse, mutect2, varscan2
- TRPC3 | c.1874G>A p.R625Q (on ENST00000379645 / NM_001366479.2; = p.R552Q on NM_003305.2) | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53372262; called by muse, mutect2, varscan2
- TSC1 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.407); catalogued as COSV53763958, COSV53765645; called by muse, mutect2, varscan2
- WDTC1 | c.1448T>A p.L483H (on ENST00000319394 / NM_001276252.2; = p.L482H on NM_015023.5) | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV60087223; called by muse, mutect2, varscan2
- XPNPEP1 | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.038); catalogued as COSV100450844; called by muse, varscan2
- ZNF277 | c.86A>G p.Y29C | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV62463287; called by muse, mutect2, varscan2
- ZSCAN9 | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs748143953, COSV52849247; called by muse, mutect2, varscan2
- SLFN5 | c.1326_1327insA p.L443Tfs*58 | Frame Shift Ins (INS) | VAF 13/107 reads (12%) | called by mutect2, pindel, varscan2
- ZNF43 | c.2256_2258del p.H752_K753delinsQ | In Frame Del (DEL) | VAF 7/28 reads (25%) | called by mutect2, pindel, varscan2
- ADGRF2 | c.447T>C p.T149= (on ENST00000296862 / NM_001368115.2; = p.T81= on NM_153839.7) | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as COSV57286605; called by muse, mutect2, varscan2
- ADGRG6 | c.3354G>A p.K1118= | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as COSV99746091; called by muse, mutect2, varscan2
- ANXA9 | c.513C>A p.T171= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV64484198; called by muse, mutect2, varscan2
- CLCN6 | c.2082C>T p.I694= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs769676991, COSV56738079; called by muse, mutect2, varscan2
- FAM107B | c.183C>T p.G61= | Silent (SNP) | VAF 56/114 reads (49%) | catalogued as rs574031893, COSV51679790; called by muse, mutect2, varscan2
- GET3 | c.759G>A p.L253= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as rs1397606956, COSV62001885; called by muse, mutect2, varscan2
- IQCF2 | c.384C>T p.I128= | Silent (SNP) | VAF 18/100 reads (18%) | catalogued as COSV60761116; called by muse, mutect2, varscan2
- IRX6 | c.996G>A p.A332= | Silent (SNP) | VAF 4/55 reads (7%) | catalogued as rs1357119251, COSV51859163; called by muse, mutect2
- MBD5 | c.3588G>A p.Q1196= | Silent (SNP) | VAF 68/143 reads (48%) | catalogued as rs1261051324, COSV68695834; called by muse, mutect2, varscan2
- MGAM | c.5286G>C p.G1762= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV72073721, COSV72075224; called by muse, mutect2
- NCAM2 | c.1026G>A p.T342= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as rs755302240, COSV53058226; called by muse, mutect2, varscan2
- PLD2 | c.1674C>T p.H558= | Silent (SNP) | VAF 10/69 reads (14%) | catalogued as rs1567531965, COSV99562087; called by muse, mutect2, varscan2
- SLAIN1 | c.1092C>T p.S364= (on ENST00000466548; = p.S101= on NM_144595.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/92 reads (7%) | catalogued as COSV99935025; called by muse, mutect2
- SLC8A3 | c.2508C>T p.I836= (on ENST00000381269 / NM_183002.3; = p.I834= on NM_033262.4) | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as rs760608803, COSV53687704; called by muse, mutect2, varscan2
- TTN | c.42192T>A p.V14064= (on ENST00000591111; = p.V6640= on NM_003319.4) | Silent (SNP) | VAF 21/100 reads (21%) | catalogued as COSV59902075; called by muse, mutect2, varscan2
- MIRLET7A2 | n.70C>T | RNA (SNP) | VAF 5/67 reads (7%) | called by muse, mutect2
- RASSF1 | c.369+679G>A | Intron (SNP) | VAF 9/34 reads (26%) | catalogued as rs1460876924, COSV51600100; called by muse, mutect2, varscan2
- WNK1 | c.2140-2374A>G | Intron (SNP) | VAF 106/302 reads (35%) | catalogued as COSV60026191; called by muse, mutect2, varscan2
